Somatic mutation profile of tumor specimen TARGET-10-PARAPT-09A (aliquot TARGET-10-PARAPT-09A-01D) from TARGET case TARGET-10-PARAPT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,577 days).
Specimen TARGET-10-PARAPT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de862e96-5805-4e4c-bfb8-fee8e882e36a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARAPT-10A (Blood Derived Normal), aliquot TARGET-10-PARAPT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c2420c3-0248-4b5e-990c-2b7ea89b53cd

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Splice Site 2, Silent 2, Nonsense Mutation 1, 5'Flank 1, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASXL2 | c.1316C>G p.S439* | Nonsense Mutation (SNP) | VAF 6/132 reads (5%) | catalogued as COSV99709888; called by muse, mutect2
- FLT3 | c.1775T>G p.V592G | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV54051432, COSV54058572, COSV54074139; called by muse, mutect2
- HDLBP | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.093); catalogued as rs758748107, COSV60494455; called by muse, mutect2, varscan2
- KCNH6 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs756068734; called by muse, mutect2, varscan2
- KIAA1109 | c.8798+1G>A p.X2933_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV52682977; called by muse, mutect2, varscan2
- TRRAP | c.11164G>T p.D3722Y (on ENST00000359863 / NM_001244580.1; = p.D3693Y on NM_003496.3) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100705490; called by muse, mutect2, varscan2
- TTLL7 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs776185188; called by muse, mutect2, varscan2
- ZDBF2 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV65622597; called by muse, mutect2, varscan2
- ASMT | c.688A>T p.I230F (on ENST00000381229; = p.I258F on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DMD | c.531-2del p.X177_splice | Splice Site (DEL) | VAF 23/155 reads (15%) | called by mutect2, pindel, varscan2
- IGLV8-61 | chr22:22099211 ins CGG | In Frame Ins (INS) | VAF 10/82 reads (12%) | called by mutect2, pindel
- EXD1 | c.984A>G p.G328= | Silent (SNP) | VAF 36/151 reads (24%) | called by muse, mutect2, varscan2
- MET | c.3423G>A p.S1141= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs567551556; ClinVar: likely benign; called by muse, mutect2, varscan2
- NELL1 | c.*87del | 3'UTR (DEL) | VAF 14/53 reads (26%) | catalogued as rs1248794553; called by mutect2, pindel, varscan2
- TRIM23 | chr5:65624377 G>A | 5'Flank (SNP) | VAF 9/49 reads (18%) | catalogued as rs959717880; called by muse, mutect2
